Gene-level copy-number profile of tumor specimen TCGA-CS-6667-01A from TCGA case TCGA-CS-6667, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Astrocytoma, NOS; Tissue or organ of origin: Brain, NOS; Tumor grade: G2; Age at diagnosis: 39.4 years (14,375 days).
Specimen TCGA-CS-6667-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LGG.671631b5-9643-4d63-9ed0-807dde19de97.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-CS-6667-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 364 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/0bac99fb-b959-4f0d-9abc-2717730bfb42

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 2,240; copy number 1: 448; copy number 2: 55,869; copy number 3: 928; copy number 4: 680; copy number 5: 1; copy number 6: 93.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-CS-6667-01A-12D-2023-01): tumor purity 0.73, ploidy 2.01, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 250 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:64,450,096–64,461,381, 2 genes: AC008074.1, LGALSL.
- chr7:3,642,815–3,643,784, 1 gene: AC011284.1.
- chr8:39,314,591–39,730,065, 4 genes (within-gene range 0–1): ADAM5, ADAM3A, AC123767.1, ADAM18.
- chr17:41,265,339–41,271,835, 2 genes: KRTAP9-6, KRTAP9-11P.
- chr17:80,351,828–83,095,122, 156 genes (within-gene range 0–3) (broad region; genes not listed).
- chr18:79,069,285–80,247,514, 38 genes: ATP9B, AC099689.3, AC125437.1, AC125437.2, AC125437.3, AC104423.1, AC023090.1, AC023090.2, NFATC1, AC018445.3, AC018445.5, AC018445.1, AC018445.4, AC018445.2, AC018445.6, AC068473.3, AC068473.4, AC068473.1, AC068473.5, CTDP1, AC068473.2, AC021594.1, AC021594.2, KCNG2, AC114341.1, SLC66A2, AC114341.2, HSBP1L1, TXNL4A, AC090360.1, RBFA, RBFADN, SLC25A6P4, ADNP2, PARD6G-AS1, PARD6G, AC139100.2, AC139100.1.
- chr20:63,639,705–64,313,132, 47 genes (within-gene range 0–2): STMN3, RTEL1, RTEL1-TNFRSF6B, TNFRSF6B, ARFRP1, ZGPAT, AL121845.3, AL121845.4, LIME1, AL121845.2, SLC2A4RG, ZBTB46, AL121845.1, ZBTB46-AS1, C20orf181, AL118506.1, ABHD16B, TPD52L2, DNAJC5, RNU1-134P, MIR941-1, MIR941-2, MIR941-3, MIR941-4, MIR941-5, UCKL1, MIR1914, MIR647, UCKL1-AS1, ZNF512B, SAMD10, PRPF6, C20orf204, SOX18, TCEA2, AL355803.1, RGS19, MIR6813, OPRL1, LKAAEAR1, AL121581.3, MYT1, NPBWR2, PCMTD2, AL137028.2, CICP4, LINC00266-1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 94 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:110,727,456–110,727,679, 1 gene, copy number 5: AL513328.1.
- chr14:105,736,343–106,318,236, 93 genes, copy number 6 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 245. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
